MMRF case MMRF_2024 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/83a79d04-1c98-4fbd-b4c2-6ea747508e8f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.7 years (21,435 days); ISS stage: III; Days to last known disease status: 976 days (2.7 years); Days to last follow up: 976 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 88 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 96 days; Days to treatment end: 200 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 248 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 374 days (1.0 years); Days to treatment end: 420 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 452 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 618 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 51.5 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 10.8 µg/mL; Lactate Dehydrogenase 4.53 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 258 µmol/L; Total Protein 9.6 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 102: Hemoglobin 6.45 mmol/L; Leukocytes 7.12 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 141 µmol/L; Total Protein 7.2 g/dL; Glucose 5.23 mmol/L.
- Day 172: M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 244 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 62.3 mg/dL; Immunoglobulin G 8.24 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 107 µmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 311 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.6 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.31 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.23 mmol/L.
- Day 374 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 157 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.3 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 20 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 466 (ECOG 1): Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 536 (ECOG 1): M Protein 0.09 g/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 634 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.39 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 25.7 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 732 (ECOG 1): Immunoglobulin G 5.91 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.23 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 22.8 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 822 (ECOG 0): M Protein 0.12 g/dL; Immunoglobulin G 5.61 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.56 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL.
- Day 906 (ECOG 0): M Protein 0.15 g/dL; Immunoglobulin G 5.82 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL.
- Day 976 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 159 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 91.8 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL.

Other clinical attributes
- Day 1: Weight: 49 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_2024_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2024_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
